Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3906, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3906-01A (Primary Tumor).

Diagnosis

Resected rectosigmoid material with a centrally ulcerated, moderately differentiated adenocarcinoma of the colorectal type, located 2.5 cm from the aboral resection margin, measuring 2.5 cm in diameter, with infiltration deep into the tunica muscularis propria to the border of the perirectal fatty tissue. Tumor-free local lymph nodes. Tumor-free colon resection margins. Tumor-free mesenteric resection margin.

Tumor stage: pT2, pN0 (0/26) pMX; G2, L0, V0, R0

Source: NCI Genomic Data Commons file 735e1810-1522-4f7c-a17d-16aeae2997c0 (TCGA-AG-3906.9B84FA3A-5777-48FB-8215-58155D55B906.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).